Surgical pathology report (de-identified scan), TCGA case TCGA-77-8128, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8128-01A (Primary Tumor).

[page 1 of 3]
Collected [REDACTED]

Histopathology Report

LEFT PNEUMONECTOMY AND MULTIPLE LYMPH NODE BIOPSIES

Clinical Details:
Ca left lung.

Five specimens submitted:

1: LEFT LUNG

Macroscopy:

The specimen consists of left lung, the upper lobe measuring 290 x 110 x 40 mm and the lower lobe measuring 275 x 110 x 65 mm. Present 30 mm from the proximal resection margin there is a white sclerotic nodule measuring 32 mm in maximal dimension. It appears to be arising from the main bronchus and where it branches into the bronchus supplying the lower lobe. The mucosa of the bronchus surrounding the tumour is somewhat nodular but this does not extend to the margin. The tumour appears to invade into adjacent lymph nodes and has a sclerotic appearance. No other lesions are seen. On sectioning of the uninvolved lung, there is some black anthracotic speckling. The tumour appears clear of the pleura by approximately 7 mm. [Sections taken: bronchial resection margin, A; peribronchial lymph nodes, B-C; tumour and proximal bronchus, D; further RS of tumour, E-G; RS right upper lobe, H; lower lobe, I].

Microscopy:

Sections show a moderately differentiated squamous cell carcinoma which is arising around large bronchi and extending into peribronchial soft tissue. Perineural permeation and areas suspicious for lymphatic invasion are seen but no blood vessel invasion is identified. Peribronchial lymph node involvement is noted. The tumour is clear of bronchial, soft tissue and pleural margins. Adjacent to the carcinoma, in situ squamous cell carcinoma is seen. Again, this is well clear of the bronchial margin. The adjacent lung shows mild emphysema.

2: HILAR NODES

Macroscopy:

The specimen consists of a piece of fatty tissue containing blackened lymph node tissue. It measures 24 x 16 x 10 mm. [Bisected and BIT].

Microscopy:

The lymph nodes show reactive changes only. There is no evidence of malignancy.

[page 2 of 3]
Collected [REDACTED]

Histopathology Report

3: NO. 5 NODE

Macroscopy:

The specimen consists of multiple fragments of tan and grey/black lymph node tissue measuring 25 x 13 x 8 mm in aggregate. [Wrapped and BIT].

Microscopy:

The lymph nodes are partially replaced by metastatic squamous cell carcinoma.

4: NO. 7 NODE

Macroscopy:

The specimen consists of multiple fragments of grey and black lymph node tissue measuring 17 x 12 x 4 mm. [Wrapped and BIT].

Microscopy:

The lymph nodes show reactive changes only. There is no evidence of malignancy.

5: NO. 9 NODE

Macroscopy:

The specimen consists of a lymph node with surrounding soft tissue measuring 17 x 8 x 5 mm. [Bisected and BIT]. [REDACTED]

Microscopy:

The lymph nodes show reactive changes only. There is no evidence of malignancy.

Summary: Left lung and mediastinal lymph nodes:

1. Moderately differentiated squamous cell carcinoma, 32 mm in maximum dimension.
2. Perineural permeation present but no blood vessel invasion seen.
3. Peribronchial and No. 5 lymph nodes contain metastatic carcinoma.
4. Carcinoma clear of surgical margins and pleura.
5. T2N2MX.

Reported by [REDACTED]
Anatomical Pathologist

[page 3 of 3]
Collected [REDACTED]

Histopathology Report

cc:
Cancer Registry
Registrar, [REDACTED]

Source: NCI Genomic Data Commons file 45703069-3a13-4d17-8228-8dce0edee24c (TCGA-77-8128.A1739AD2-A2DF-4DC7-A15A-0DB128651B03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).